Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GQ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GQ-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: Stomach cancer

GROSS:

Specimen submitted:

Total gastrectomy, unfixed and tissue labeled 'mesocolon'

Measurement:

[For stomach]

Greater curvature 30.0 cm
Lesser curvature 14.0 cm
Proximal resection margin 6.0 cm
Distal resection margin 6.0 cm
Esophagus 1.0 cm
Duodenum 0.5 cm

[For tissue labeled 'mesocolon']

One piece, 4.0 x 1.7 x 0.4 cm

Tumor location:

Stomach: Lower 1/3 (antrum)

From proximal resection margin - 7.0 cm

From distal resection margin - 4.0 cm

Tumor size: 10.0 x 6.0 x 1.6 cm

Tumor type: AGC (Borrmann type) III

Gross serosal invasion: Yes

Representative sections are submitted.

Gross photo: Present

Blocks

11-8, tumor and surrounding tissue x 8

A, antral mucosa x 1

B, body mucosa x 1

P, proximal resection margin of main specimen x 1

PRM, separately submitted 'proximal resection margin' x 1

D, distal resection margin x 1

LN1-4, superior gastric lymph nodes x 4

LN5-13, inferior gastric lymph nodes x 9

LN4, '1' lymph nodes x 1

LN15, '2' lymph nodes x 1

LN16, '4sa' lymph nodes x 1

LN17, '4sb' lymph nodes x 1

1CD-0-3

adenocarcinoma, tubular 8211/3

Site: Stomach, antrum C16.3

hw 9/21/12

[page 2 of 3]
LN18, '5' lymph nodes x 1
LN19-21, '6' lymph nodes x 3
LN22, '7' lymph nodes x 1
LN23-24, '9' lymph nodes x 2
LN25, '10' lymph nodes x 1
LN26, '11P' lymph nodes x 1
LN27, '11D' lymph nodes x 1
LN28, '12' lymph nodes x 1

A1-2, tissue labeled 'mesocolon' x 2

MICROSCOPIC:

Tumor type: Adenocarcinoma, tubular moderately differentiated

Depth of tumor invasion:

T4: T4b-Tumor invades adjacent structures (peripancreatic fat and mesocolon)

Margins: Proximal resection margin (-)

Distal resection margin (-)

Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Present

Lymphovascular invasion: Present

Perineural invasion: Present

Lymph node metastases:

N2: Metastasis in 3-6 regional lymph nodes

number of involved nodes 4 total number of nodes 105

perinodal extension: Yes

Distance metastasis: Not applicable

Pathologic stage: pT4bN2Mx (AJCC 7th edition)

SPECIAL STAIN:

Cresyl Violet stain reveals moderate amount of H. pylori.

Adenocarcinoma

DIAGNOSIS:

Stomach, total gastrectomy:

Adenocarcinoma, moderately differentiated, infiltrating
(advanced gastric cancer)

Lymph node, perigastric, total gastrectomy:

Superior gastric: No tumor present (0/16)

Inferior gastric: Metastatic carcinoma, primary in stomach (4/49)

Lymph node, regional, biopsy:

Labeled '1': No tumor present (0/3)

Labeled '2': No tumor present (0/6)

Labeled '4sa': No tumor present (0/2)

Labeled '4sb': No tumor present (0/2)

Labeled '5': No tumor present (0/1)

Labeled '6': No tumor present (0/7)

[page 3 of 3]
Labeled '7': No tumor present (0/4)
Labeled '9': No tumor present (0/10)
Labeled '10': No tumor present (0/1)
Labeled '11P': No tumor present (0/1)
Labeled '11D': No tumor present (0/2)
Labeled '12': No tumor present (0/1)

Tissue labeled 'mesocolon', biopsy:
Chronic inflammation, no tumor present

Handwritten initials: EMD

Source: NCI Genomic Data Commons file 96c2d2cc-6814-4aea-ba3d-d022b53be6b3 (TCGA-HU-A4GQ.5ED987B0-2EDB-4848-9E52-FCDC799937B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).